Somatic mutation profile of tumor specimen 0DFDC9 from CCDI case PBBRZX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,439 days).
Specimen 0DFDC9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2079047d-1f80-4ac0-b725-891eefdfc7b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFDAP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e049a7-1052-4273-b6ec-27dfb54282fe

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 3, RNA 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD7 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 396/576 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs572984971, COSV54135194; called by muse, varscan2
- HUWE1 | c.9131G>A p.R3044Q | Missense Mutation (SNP) | VAF 150/378 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs1556928475; called by muse, varscan2
- INPP5D | c.2977C>A p.P993T (on ENST00000445964 / NM_001017915.3; = p.P992T on NM_005541.5) | Missense Mutation (SNP) | VAF 170/324 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs1469739224; called by muse, varscan2
- NIPBL | c.5168G>A p.R1723Q | Missense Mutation (SNP) | VAF 184/434 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs886060558; ClinVar: uncertain significance; called by muse, varscan2
- NUP205 | c.2968C>G p.L990V | Missense Mutation (SNP) | VAF 213/810 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs761560315, COSV53664341; called by muse, varscan2
- RFX7 | c.851G>A p.S284N (on ENST00000559447 / NM_001368074.1; = p.S381N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/288 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs748110366; called by muse, varscan2
- SPANXB1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 279/2409 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.947); catalogued as rs1482019750; called by muse, varscan2
- TP53RK | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 136/376 reads (36%) | catalogued as rs1211533115, COSV100927796; called by muse, varscan2
- ZAN | c.2771C>T p.T924M | Missense Mutation (SNP) | VAF 238/492 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs201051040; called by muse, varscan2
- ZNF559 | c.309C>G p.H103Q | Missense Mutation (SNP) | VAF 156/530 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV57835283; called by muse, varscan2
- CARMIL2 | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 273/559 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, varscan2
- GFOD1 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 137/1014 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- NFIC | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 117/444 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RB1 | c.1027_1028del p.L343Sfs*3 | Frame Shift Del (DEL) | VAF 82/165 reads (50%) | called by pindel, varscan2
- CCDC168 | c.2511G>A p.T837= | Silent (SNP) | VAF 142/452 reads (31%) | catalogued as rs552653576; called by muse, varscan2
- FRMPD3 | c.2970G>A p.S990= | Silent (SNP) | VAF 125/334 reads (37%) | catalogued as rs777978135; called by muse, varscan2
- TRPM1 | c.2241C>T p.P747= | Silent (SNP) | VAF 134/394 reads (34%) | catalogued as rs376623689; called by muse, varscan2
- ZBTB33 | c.1209C>T p.G403= | Silent (SNP) | VAF 101/252 reads (40%) | catalogued as rs377285531; called by muse, varscan2
- FBXL21P | n.1632A>T | RNA (SNP) | VAF 58/154 reads (38%) | called by muse, varscan2
- PFKM | c.1413-52C>A | Intron (SNP) | VAF 68/202 reads (34%) | called by muse, varscan2
- SP100 | c.108-2417del | Intron (DEL) | VAF 10/91 reads (11%) | called by pindel, varscan2
- SULT1A1 | c.148+10G>A | Intron (SNP) | VAF 136/334 reads (41%) | called by muse, varscan2
